HCMI case HCM-BROD-0414-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ee0d306f-e708-478b-8bad-6f9f3bedefbf

Demographics
Sex at birth: male; Year of birth: 1964; Vital status: Dead; Days to death: 216 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 53.8 years (19,635 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Liver.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 19 days; Days to treatment end: 124 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 124 days; Days to treatment end: 191 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 201 days; Days to treatment end: 202 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 13 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 13 days.
- Follow-up contact recording only the day: day 206.

Molecular and laboratory tests
- CDKN2A mutation, nos: Negative.
- GNAS mutation, nos: Negative.
- KRAS substitution: Positive; Amino-acid change: p.Gln61His.
- RNF43 mutation, nos: Negative.
- TP53 substitution: Positive; Amino-acid change: Y126C.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 71 kg; Height: 183 cm; BMI: 21.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0414-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0414-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
